Gene-level copy-number profile of tumor specimen TCGA-DU-7010-01A from TCGA case TCGA-DU-7010, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 58.0 years (21,199 days).
Specimen TCGA-DU-7010-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.003f5063-2d5a-4da5-aa5a-30e54d5ff497.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DU-7010-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/29375b85-3c6a-4939-8916-5759ccba134b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 220; copy number 2: 5,415; copy number 3: 17,683; copy number 4: 23,462; copy number 5: 5,567; copy number 6: 6,820; copy number 7: 335; copy number 8: 114; copy number 9: 13; copy number 10: 136; copy number 11: 2; copy number 14: 3; copy number 40: 4; copy number 46: 12; copy number 51: 7; copy number 55: 2; copy number 56: 1; copy number 57: 3; copy number 58: 2; copy number 70: 2; copy number 78: 2; copy number 79: 3; copy number 85: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DU-7010-01A-11D-2023-01): tumor purity 0.75, ploidy 3.87, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 193 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:104,864,464–105,137,157, 4 genes, copy number 57–70 (within-gene range 4–70): LIN28B-AS1, LIN28B, RNU6-1106P, BVES.
- chr6:105,279,016–105,667,998, 6 genes, copy number 55–58 (within-gene range 3–58): AL133406.2, AL133406.1, RPL35P3, AL096794.1, LINC02836, Z97206.1.
- chr6:105,904,373–106,325,791, 7 genes, copy number 51: RN7SKP211, PRDM1, ATG5, AL022067.1, U4, RN7SL47P, RNU6-344P.
- chr6:106,360,717–106,572,017, 1 gene, copy number 9 (within-gene range 4–46): CRYBG1.
- chr6:106,449,381–107,133,170, 15 genes, copy number 9–46: RNA5SP211, AL109920.1, Y_RNA, RTN4IP1, RNU6-527P, QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587, CD24, MTRES1, BEND3, RNU6-1299P.
- chr7:130,791,264–131,110,176, 9 genes, copy number 9 (within-gene range 4–9): AC016831.6, AC016831.3, LINC00513, MIR29A, AC016831.1, MIR29B1, AC016831.4, AC058791.1, LINC-PINT.
- chr12:66,189,195–66,257,434, 4 genes, copy number 11–78 (within-gene range 3–78): IRAK3, RBMS1P1, MIR6502, AC078889.1.
- chr18:670,318–8,406,861, 136 genes, copy number 10 (within-gene range 8–10) (broad region; genes not listed).
- chr19:39,776,595–39,786,291, 1 gene, copy number 85: LEUTX.
- chr19:44,699,151–44,760,044, 3 genes, copy number 14: CEACAM16, AC243964.2, BCL3.
- chr19:51,560,122–51,592,510, 3 genes, copy number 79 (within-gene range 4–79): AC020914.4, SIGLEC29P, ZNF175.
- chr19:52,797,408–52,857,649, 3 genes, copy number 40: ZNF28, PABPN1P2, ZNF468.
- chr19:52,865,369–52,865,429, 1 gene, copy number 40: AC010487.2.

Autosomal genes at a single copy (total copy number 1): 220. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
